Somatic mutation profile of tumor specimen ER-ADXD-TTP1-A (aliquot ER-ADXD-TTP1-A-1-0-D-A540-34) from EXCEPTIONAL_RESPONDERS case ER-ADXD, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Overlapping lesion of colon; Age at diagnosis: 69.4 years (25,357 days).
Specimen ER-ADXD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68642049-267a-4925-9939-488f89d62711.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ADXD-NT1-A (Solid Tissue Normal), aliquot ER-ADXD-NT1-A-1-0-D-A540-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d687ae85-6c34-4cea-82b5-757125d730de

The open-access MAF lists 108 somatic variants for this specimen: 78 protein-altering or splice-affecting, 23 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 23, Nonsense Mutation 5, Frame Shift Del 4, 5'UTR 3, Intron 3, Frame Shift Ins 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DUOX2 | c.3115C>T p.R1039W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752176935; ClinVar: likely pathogenic; called by mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 72/189 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSBG2 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as rs142290585, COSV53124454; called by muse, mutect2, varscan2
- APC | c.4192del p.S1398Vfs*17 | Frame Shift Del (DEL) | VAF 27/60 reads (45%) | catalogued as CD054298; called by mutect2, pindel, varscan2
- C16orf46 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs753410237, COSV55150646; called by muse, mutect2, varscan2
- CACNA1E | c.5444C>A p.T1815K | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1032526065; called by muse, mutect2, varscan2
- CDH8 | c.182G>T p.R61I | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99076732; called by muse, mutect2, varscan2
- CEACAM4 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs201492288, COSV55731164; called by muse, mutect2, varscan2
- CFAP54 | c.5671C>T p.R1891* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as rs776966513, COSV61576161; called by muse, mutect2, varscan2
- CLCNKB | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.437); catalogued as rs145862077; called by muse, mutect2, varscan2
- CYTH3 | c.967C>T p.R323W (on ENST00000396741; = p.R322W on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs760840529, COSV60360758, COSV60363541; called by muse, mutect2, varscan2
- DRGX | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764345451, COSV65137777; called by muse, varscan2
- ELK4 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs747854041, COSV56983819; called by muse, mutect2, varscan2
- FNDC1 | c.3881C>T p.P1294L | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs769296623, COSV99797116; called by muse, mutect2
- FSIP2 | c.16365C>A p.C5455* | Nonsense Mutation (SNP) | VAF 16/103 reads (16%) | catalogued as rs573695530; called by muse, mutect2, varscan2
- GPR52 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs575108337, COSV52307757, COSV99266723; called by muse, mutect2, varscan2
- GRAMD1B | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs1331085646, COSV59202167; called by muse, mutect2, varscan2
- GRIK5 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs767198962, COSV53484044; called by muse, mutect2, varscan2
- IBSP | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs1252338674, COSV56895782, COSV56896429; called by muse, mutect2, varscan2
- KCND1 | c.1604G>T p.R535L | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.949); catalogued as rs781797726, COSV54414521; called by muse, mutect2, varscan2
- KIF20B | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1017139052; called by muse, mutect2, varscan2
- KRTAP24-1 | c.285C>A p.C95* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as rs777321895; called by muse, mutect2, varscan2
- MAGEA6 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 24/40 reads (60%) | catalogued as COSV61449188; called by muse, mutect2, varscan2
- MMP12 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1555009338, COSV58259103; called by muse, varscan2
- MMRN1 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); catalogued as rs762148913, COSV53333574; called by muse, mutect2, varscan2
- NECAB1 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs778432411, COSV101341109; called by muse, mutect2, varscan2
- OR3A1 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs142429357; called by muse, varscan2
- OR6B3 | c.638C>A p.A213D | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs747734608; called by muse, mutect2, varscan2
- PKD1L1 | c.5216G>A p.S1739N | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV104389772; called by muse, mutect2, varscan2
- POLQ | c.7580G>A p.C2527Y | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs943784048; called by muse, mutect2, varscan2
- PRDM16 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748880850, COSV54582073; called by muse, mutect2, varscan2
- RHAG | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs976240588, COSV57706500, COSV57706736; called by muse, mutect2, varscan2
- RTL1 | c.2344G>A p.V782I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375511258, COSV66016386; called by mutect2, varscan2
- SLC49A4 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs1333348105; called by muse, mutect2, varscan2
- SMAD2 | c.911A>T p.D304V | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100054307, COSV50993184; called by muse, mutect2, varscan2
- SND1 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs889429536; called by muse, varscan2
- TRAPPC12 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.166); catalogued as COSV100160595; called by muse, varscan2
- TRPV5 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.243); catalogued as rs760942343; called by muse, mutect2, varscan2
- TTN | c.6958C>T p.R2320C (on ENST00000591111; = p.R2274C on NM_003319.4) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | PolyPhen probably damaging (0.998); catalogued as rs776478343, COSV59938269; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- ZBTB41 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV66360419; called by muse, mutect2, varscan2
- ZFHX4 | c.4141C>G p.Q1381E | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV51486212, COSV99259970; called by muse, mutect2, varscan2
- AHNAK | c.14182T>G p.L4728V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); called by muse, mutect2
- ANKRD24 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP2A3 | c.1384C>A p.L462M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- BPIFC | c.56A>G p.Y19C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1orf68 | c.14A>T p.Q5L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNA1A | c.279del p.I94Sfs*10 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- CCDC66 | c.611T>G p.F204C (on ENST00000394672 / NM_001353147.1; = p.F170C on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- COL9A1 | c.1871C>A p.P624H | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DES | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); called by muse, varscan2
- ECPAS | c.2440A>T p.I814F | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- EYS | c.4112T>C p.M1371T | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLI2 | c.4463T>A p.L1488Q (on ENST00000361492 / NM_001374353.1; = p.L1505Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GLS | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPC2 | c.972C>G p.I324M | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- HMCN2 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- IQCA1 | c.856A>C p.K286Q | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIF20B | c.2018T>G p.V673G | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- KPNB1 | c.2242G>T p.D748Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- LRRC66 | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- METTL3 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- NOX4 | c.1194C>A p.F398L | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.012); called by muse, mutect2
- PASD1 | c.1522A>G p.K508E | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.193); called by mutect2, varscan2
- PCDHA4 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PI4K2B | c.1078dup p.Y360Lfs*17 | Frame Shift Ins (INS) | VAF 26/187 reads (14%) | called by mutect2, varscan2
- PI4K2B | c.1078+1delinsTA p.X360_splice | Splice Site (INS) | VAF 25/214 reads (12%) | called by mutect2*, pindel, varscan2*
- PODNL1 | c.618C>A p.S206R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- PRPSAP1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, varscan2
- RYR3 | c.7946C>T p.T2649I (on ENST00000389232; = p.T2650I on NM_001036.6) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2
- SETD5 | c.404C>A p.A135E | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SKIDA1 | c.382dup p.R128Pfs*47 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- SMAD4 | c.1619_1625del p.L540Pfs*10 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- SNX27 | c.416A>T p.E139V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TBC1D4 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, varscan2
- TRMT13 | c.421del p.I141Lfs*24 | Frame Shift Del (DEL) | VAF 33/142 reads (23%) | called by mutect2, pindel, varscan2
- VSTM2B | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCA3 | c.2079G>A p.S693= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs977720309; called by muse, varscan2
- ADGB | c.3813G>A p.Q1271= | Silent (SNP) | VAF 52/192 reads (27%) | called by muse, mutect2, varscan2
- AR | c.411C>T p.A137= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs1308331665; called by muse, mutect2, varscan2
- C6orf52 | c.453G>A p.P151= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs952048744, COSV52584463; called by muse, mutect2, varscan2
- CCS | c.789C>A p.G263= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
- COL1A2 | c.2442G>C p.G814= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV51953435; called by muse, mutect2, varscan2
- ELOA2 | c.2253C>T p.S751= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- GBX1 | c.333G>T p.P111= | Silent (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2, varscan2
- HEATR6 | c.1083C>G p.P361= | Silent (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- HOXB1 | c.342G>A p.S114= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs774621120, COSV53318586; called by mutect2, varscan2
- KLHDC7A | c.1869C>T p.F623= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1397426862, COSV68769610; called by muse, mutect2
- LHFPL1 | c.654C>A p.L218= | Silent (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- MMRN2 | c.2271C>T p.N757= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- PCDHA2 | c.2091C>T p.N697= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV65367452; called by muse, mutect2, varscan2
- PLXNA4 | c.4425C>T p.D1475= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs376463343; called by muse, mutect2, varscan2
- PTCHD4 | c.2505A>G p.E835= | Silent (SNP) | VAF 28/133 reads (21%) | called by muse, mutect2, varscan2
- PXDN | c.2674C>T p.L892= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- QSER1 | c.1593G>A p.Q531= (on ENST00000399302; = p.Q660= on NM_001076786.3) | Silent (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- SLC34A1 | c.12C>T p.Y4= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs747607849; called by muse, mutect2, varscan2
- TCERG1 | c.966T>A p.P322= | Silent (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- TCF3 | c.456C>T p.S152= | Silent (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- TTN | c.18720T>C p.N6240= (on ENST00000591111; = p.N5313= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs760847894; called by muse, mutect2, varscan2
- TTYH1 | c.9G>A p.A3= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs952967398; called by muse, mutect2, varscan2
- CYTH4 | c.547+887A>C | Intron (SNP) | VAF 5/25 reads (20%) | catalogued as rs1362929522; called by muse, mutect2, varscan2
- DNAJB8 | c.-681G>A | 5'UTR (SNP) | VAF 19/44 reads (43%) | catalogued as rs1001895907; called by muse, mutect2, varscan2
- LGI4 | c.793+16G>A | Intron (SNP) | VAF 6/22 reads (27%) | catalogued as rs759509868; called by muse, mutect2, varscan2
- MAP1A | c.-37G>T | 5'UTR (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- SPINT5P | n.153dup | RNA (INS) | VAF 34/131 reads (26%) | catalogued as rs368100812; called by mutect2, pindel, varscan2
- TET2 | c.3501-571G>A | Intron (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- TMEM8B | c.-781C>T | 5'UTR (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
